Somatic mutation profile of tumor specimen C3L-04911-01 (aliquot CPT0424350006) from CPTAC case C3L-04911, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 83.9 years (30,659 days).
Specimen C3L-04911-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1caa705-6787-45f9-9878-b9473f9512e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04911-32 (Blood Derived Normal), aliquot CPT0424500006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/392e4daf-c643-438c-b7ab-d1b5a1a541f1

The open-access MAF lists 219 somatic variants for this specimen: 163 protein-altering or splice-affecting, 49 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 49, Nonsense Mutation 12, Intron 4, Splice Site 4, In Frame Del 2, Frame Shift Del 1, RNA 1, 5'Flank 1, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 28/337 reads (8%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2
- AAMDC | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 33/407 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs754956539, COSV100489888; called by muse, mutect2
- ACCSL | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 65/372 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as rs372214310; called by muse, mutect2, varscan2
- AFF3 | c.1774G>A p.E592K | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs751544630, COSV100420262; called by muse, mutect2, varscan2
- ALDH1A2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1179037754, COSV99990713; called by muse, mutect2, varscan2
- ANKRD50 | c.2170A>G p.S724G | Missense Mutation (SNP) | VAF 32/459 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs1306501265; called by muse, mutect2
- ATM | c.5882A>G p.Y1961C | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs56399311, CM094670, COSV53755628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP6 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 65/496 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1390806882; called by muse, mutect2, varscan2
- C2orf69 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 59/375 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.055); catalogued as rs1022042628; called by muse, mutect2, varscan2
- C8orf34 | c.233T>C p.L78P | Missense Mutation (SNP) | VAF 32/490 reads (7%) | SIFT tolerated, low confidence (0.14); catalogued as COSV62073693; called by muse, mutect2
- CACTIN | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV50266954; called by muse, mutect2, varscan2
- CDH9 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 30/140 reads (21%) | catalogued as COSV50251677, COSV99144966; called by muse, mutect2, varscan2
- CEP19 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 27/524 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356324447; called by muse, mutect2
- CNGB3 | c.2207A>G p.E736G | Missense Mutation (SNP) | VAF 23/362 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs754176697; called by muse, mutect2
- CPEB2 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious, low confidence (0); catalogued as rs1240377542; called by muse, mutect2, varscan2
- CTXN3 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65218585; called by muse, mutect2
- DCAF12L1 | c.1392A>C p.*464Yext*2 | Nonstop Mutation (SNP) | VAF 18/224 reads (8%) | catalogued as COSV100948081; called by muse, mutect2
- DNAH17 | c.9557C>T p.A3186V | Missense Mutation (SNP) | VAF 50/488 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs747233018, COSV67750093; called by muse, mutect2
- EDNRB | c.299G>A p.R100H (on ENST00000377211 / NM_001201397.1; = p.R10H on NM_000115.5) | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.001); catalogued as COSV57519857, COSV57524856; called by muse, mutect2, varscan2
- EXOSC9 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as COSV99696956; called by muse, mutect2
- EZHIP | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 33/254 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1276206963; called by muse, mutect2, varscan2
- F13B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 48/386 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FAM110B | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 34/481 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.254); catalogued as rs1333658589, COSV64064894, COSV64066564; called by muse, mutect2
- FAT3 | c.3322C>T p.R1108W | Missense Mutation (SNP) | VAF 56/333 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs368324627, COSV53111539; called by muse, mutect2, varscan2
- FAT3 | c.8975G>T p.R2992I | Missense Mutation (SNP) | VAF 14/418 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53176466; called by muse, mutect2
- FGD2 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs377492771, COSV51463112; called by muse, mutect2, varscan2
- GABRG3 | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 80/276 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV61515829; called by muse, mutect2, varscan2
- GSPT2 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 16/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782749160; called by muse, mutect2
- H4C12 | c.59G>A p.R20H | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as rs781309459, COSV100694834; called by muse, mutect2, varscan2
- HEATR5B | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777454095; called by muse, mutect2, varscan2
- HECW1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); catalogued as rs532143087, COSV67829190; called by muse, mutect2, varscan2
- IFTAP | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57559425; called by muse, mutect2
- ITGAD | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as rs754577254, COSV101210442; called by muse, mutect2
- ITPKC | c.1501C>T p.R501W | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769556058; called by muse, mutect2
- KDM4A | c.2153C>T p.T718M | Missense Mutation (SNP) | VAF 44/408 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs774525009; called by muse, mutect2, varscan2
- KRTAP4-9 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 162/753 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1192074916; called by muse, mutect2, varscan2
- LRFN5 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 10/326 reads (3%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV99985359; called by muse, mutect2
- MAGEC1 | c.1603A>C p.S535R | Missense Mutation (SNP) | VAF 23/422 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.485); catalogued as COSV53576808, COSV53578796; called by muse, mutect2
- MAPK10 | c.127G>A p.A43T (on ENST00000359221 / NM_001351625.2; = p.A81T on NM_002753.5) | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1416981784, COSV60387180; called by muse, mutect2, varscan2
- MUC17 | c.6422C>A p.S2141* | Nonsense Mutation (SNP) | VAF 18/558 reads (3%) | catalogued as COSV60284954; called by muse, mutect2
- MUC6 | c.6601_6603del p.S2201del | In Frame Del (DEL) | VAF 136/589 reads (23%) | catalogued as rs1296850164; called by pindel, varscan2
- MYCT1 | c.44C>G p.S15C | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV65891952; called by muse, mutect2, varscan2
- MYH14 | c.3851G>A p.R1284Q | Missense Mutation (SNP) | VAF 116/375 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.93); catalogued as rs201181045, COSV51813286; called by muse, mutect2, varscan2
- NAP1L3 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV59073413; called by muse, mutect2, varscan2
- NCAPD3 | c.3895G>A p.V1299I | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs1041107351; called by muse, mutect2, varscan2
- NSMCE1 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs769578125; called by muse, mutect2, varscan2
- NUP93 | c.2006C>G p.S669C | Missense Mutation (SNP) | VAF 9/252 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV100359836; called by muse, mutect2
- OR10R2 | c.520T>G p.L174V | Missense Mutation (SNP) | VAF 40/443 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.12); catalogued as COSV63768399, COSV63769239; called by muse, mutect2
- OR5W2 | c.94T>A p.L32M | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV60614714, COSV60614862; called by muse, mutect2
- OVCH1 | c.2503C>A p.P835T | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs1361284151; called by muse, mutect2, varscan2
- PARP8 | c.1085T>G p.L362R | Missense Mutation (SNP) | VAF 34/440 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV55866808; called by muse, mutect2
- PCDH17 | c.386C>T p.A129V | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.594); catalogued as COSV64980270; called by muse, mutect2, varscan2
- PCDH8 | c.1882G>A p.A628T | Missense Mutation (SNP) | VAF 80/415 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1373436783; called by muse, mutect2, varscan2
- PCDHA9 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 59/622 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs545192815, COSV65329164; called by muse, mutect2, varscan2
- PCDHGA6 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as rs769413254; called by muse, mutect2, varscan2
- PCK2 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 38/406 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99394079; called by muse, mutect2
- PEG3 | c.3823A>C p.S1275R | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as COSV55629227, COSV55642916; called by muse, mutect2
- PPP2R2D | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs782030666; called by muse, mutect2
- PRRC2B | c.5494C>T p.R1832W | Missense Mutation (SNP) | VAF 21/287 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754297872; called by muse, mutect2
- PRSS12 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 40/339 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs183410755, COSV99627604; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 13/233 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, mutect2
- RAD54L | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 71/492 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.653); catalogued as rs372007047; called by muse, mutect2, varscan2
- RBP3 | c.2119G>A p.E707K | Missense Mutation (SNP) | VAF 51/365 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.181); catalogued as rs782314171; called by muse, mutect2, varscan2
- RFX2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 80/287 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs200963067, COSV57941756; called by muse, mutect2, varscan2
- RIMS1 | c.1228G>A p.G410S | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1341234255; called by muse, mutect2
- SCN5A | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.249); catalogued as rs756474485, CM139913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.6170A>C p.D2057A | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101269275; called by muse, mutect2
- SH3BP4 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs199774203; called by muse, mutect2, varscan2
- SIN3A | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as rs749564136, COSV100845079; called by muse, mutect2, varscan2
- SLC17A6 | c.1157A>T p.K386M | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54139338; called by muse, mutect2, varscan2
- SLC8A1 | c.167A>C p.K56T | Missense Mutation (SNP) | VAF 19/509 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV60479849; called by muse, mutect2
- SLCO1B3 | c.1268T>G p.L423R | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53947409; called by muse, mutect2
- SLITRK5 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 103/404 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280151; called by muse, mutect2, varscan2
- SNAP91 | c.830C>T p.T277M | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758802743, COSV52114323; called by muse, mutect2
- SOX5 | c.2140G>A p.G714S | Missense Mutation (SNP) | VAF 101/415 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs183456814, COSV99057268; called by muse, mutect2, varscan2
- SPTY2D1 | c.174A>C p.K58N | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60473143; called by muse, mutect2
- SRGAP3 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 111/412 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs775488458, COSV100840581; called by muse, mutect2, varscan2
- SSRP1 | c.2090C>T p.P697L | Missense Mutation (SNP) | VAF 64/429 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs757540521; called by muse, mutect2, varscan2
- STX11 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 48/418 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845551; called by muse, mutect2, varscan2
- SULF1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1387439634, COSV52678242; called by muse, mutect2, varscan2
- TLR2 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs745621022, COSV52607568; called by muse, mutect2
- TRAF5 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.649); catalogued as rs1051278632; called by muse, mutect2, varscan2
- UNC79 | c.4183C>T p.R1395W (on ENST00000393151 / NM_001346218.2; = p.R1218W on NM_020818.5) | Missense Mutation (SNP) | VAF 48/557 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769549721, COSV56378995; called by muse, mutect2
- ZFHX4 | c.3385T>C p.S1129P | Missense Mutation (SNP) | VAF 30/286 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1039776769; called by muse, mutect2, varscan2
- AATK | c.2206G>A p.A736T (on ENST00000326724 / NM_001080395.3; = p.A633T on NM_004920.2) | Missense Mutation (SNP) | VAF 50/617 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.049); called by muse, mutect2
- ABCA8 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 46/379 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.211); called by muse, mutect2
- ACACA | c.5135G>A p.R1712Q | Missense Mutation (SNP) | VAF 20/595 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACIN1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 75/348 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADGRL3 | c.1211G>T p.G404V (on ENST00000506720 / NM_001322402.2; = p.G336V on NM_015236.6) | Missense Mutation (SNP) | VAF 31/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ATP2B1 | c.2068G>C p.V690L | Missense Mutation (SNP) | VAF 22/303 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- BMT2 | c.1159A>C p.S387R | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- BPTF | c.1636A>C p.K546Q | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2
- BTBD7 | c.3160G>T p.V1054F | Missense Mutation (SNP) | VAF 131/536 reads (24%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC88A | c.3775A>C p.K1259Q | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.007); called by muse, mutect2
- CDYL | c.501T>G p.F167L (on ENST00000328908 / NM_001368125.1; = p.F113L on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- CERKL | c.898+1G>A p.X300_splice (on ENST00000339098 / NM_001030311.2; = p.X274_splice on NM_201548.5) | Splice Site (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- CHP2 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 80/350 reads (23%) | called by muse, mutect2, varscan2
- CLDN17 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- CSDE1 | c.2032G>A p.V678M (on ENST00000358528 / NM_001007553.3; = p.V647M on NM_007158.6) | Missense Mutation (SNP) | VAF 25/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CTDP1 | c.485G>A p.S162N | Missense Mutation (SNP) | VAF 75/327 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CUBN | c.60A>C p.E20D | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.075); called by muse, mutect2
- DCLK2 | c.2074-23_2090del p.X692_splice | Splice Site (DEL) | VAF 30/198 reads (15%) | called by mutect2, pindel, varscan2
- DCLK3 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 38/442 reads (9%) | called by muse, mutect2
- DEFB113 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- DPY19L2 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 34/429 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, mutect2
- E2F8 | c.615G>C p.Q205H | Missense Mutation (SNP) | VAF 56/427 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- EDA2R | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- EYA4 | c.1163T>G p.V388G (on ENST00000531901 / NM_001301013.1; = p.V382G on NM_004100.5) | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2
- FAT3 | c.5582T>C p.L1861P | Missense Mutation (SNP) | VAF 19/414 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- FCER1A | c.397C>T p.H133Y | Missense Mutation (SNP) | VAF 34/388 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); called by muse, mutect2
- FKBP15 | c.864+1G>T p.X288_splice | Splice Site (SNP) | VAF 30/298 reads (10%) | called by muse, mutect2
- GPR158 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 66/730 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2
- GRIA4 | c.2135T>G p.V712G | Missense Mutation (SNP) | VAF 12/392 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HNRNPM | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 33/253 reads (13%) | called by muse, mutect2, varscan2
- HPSE | c.1490G>A p.G497D | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- HSF1 | c.1447A>G p.T483A | Missense Mutation (SNP) | VAF 84/430 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IRF2BPL | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.962); called by muse, varscan2
- KCNB2 | c.1002A>C p.E334D | Missense Mutation (SNP) | VAF 91/496 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH5 | c.2114C>A p.P705Q | Missense Mutation (SNP) | VAF 50/414 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KDM3B | c.4231C>T p.Q1411* | Nonsense Mutation (SNP) | VAF 49/224 reads (22%) | called by muse, mutect2, varscan2
- KIF26B | c.2562C>A p.Y854* | Nonsense Mutation (SNP) | VAF 84/654 reads (13%) | called by muse, mutect2, varscan2
- KIF5A | c.877G>A p.G293R | Missense Mutation (SNP) | VAF 55/381 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- L3MBTL4 | c.1683T>A p.H561Q | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, varscan2
- LAMA2 | c.1192T>C p.F398L | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- MICAL2 | c.4487G>A p.R1496K | Missense Mutation (SNP) | VAF 16/418 reads (4%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.024); called by muse, mutect2
- MICAL3 | c.1948C>T p.P650S | Missense Mutation (SNP) | VAF 43/353 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MPP7 | c.393C>G p.D131E | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MTUS2 | c.940T>C p.Y314H | Missense Mutation (SNP) | VAF 115/411 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC15 | c.601T>C p.F201L | Missense Mutation (SNP) | VAF 28/338 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); called by muse, mutect2
- MUC6 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- MYH2 | c.3974T>C p.L1325P | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NBPF15 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 18/577 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- NME8 | c.1015A>C p.K339Q | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- OGDH | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR3A2 | c.529T>G p.F177V | Missense Mutation (SNP) | VAF 21/599 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR51I2 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 35/376 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- OTOG | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 34/343 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2
- PABPC1L2B | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PEPD | c.1186A>C p.S396R | Missense Mutation (SNP) | VAF 120/395 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIEZO2 | c.5555A>C p.N1852T | Missense Mutation (SNP) | VAF 56/514 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0); called by mutect2, varscan2
- PLEKHD1 | c.621G>T p.E207D | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRODH2 | c.490G>C p.E164Q (on ENST00000301175; = p.E88Q on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RAB11FIP1 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); called by muse, mutect2
- RAG1 | c.2688G>A p.W896* | Nonsense Mutation (SNP) | VAF 96/444 reads (22%) | called by muse, mutect2, varscan2
- ROBO1 | c.3993A>C p.E1331D | Missense Mutation (SNP) | VAF 34/446 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- RYR1 | c.9382A>G p.N3128D | Missense Mutation (SNP) | VAF 103/351 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SFMBT2 | c.575T>G p.I192R | Missense Mutation (SNP) | VAF 54/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SFSWAP | c.2791-1G>A p.X931_splice | Splice Site (SNP) | VAF 30/256 reads (12%) | called by muse, mutect2, varscan2
- SLC39A4 | c.1667G>A p.R556H (on ENST00000301305 / NM_001374839.1; = p.R531H on NM_017767.3) | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- SLC5A9 | c.882T>A p.C294* | Nonsense Mutation (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- SLC6A14 | c.117G>C p.W39C | Missense Mutation (SNP) | VAF 29/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC1B | c.3561_3563del p.E1188del | In Frame Del (DEL) | VAF 58/272 reads (21%) | called by pindel, varscan2
- SRSF8 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 18/490 reads (4%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.432); called by muse, mutect2
- TBC1D9 | c.848A>G p.K283R | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- THSD7A | c.4589A>T p.E1530V | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- TIMM23B | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- TMEM184B | c.949A>T p.K317* | Nonsense Mutation (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- TNC | c.5800G>A p.G1934S | Missense Mutation (SNP) | VAF 26/240 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- TRDN | c.1680A>C p.K560N | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.544); called by muse, mutect2
- TRUB2 | c.790A>G p.T264A | Missense Mutation (SNP) | VAF 41/406 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2
- TTC28 | c.7096A>G p.S2366G | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); called by muse, mutect2
- VPS51 | c.2314C>G p.P772A | Missense Mutation (SNP) | VAF 49/343 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- WIPI2 | c.125_128del p.V42Gfs*3 | Frame Shift Del (DEL) | VAF 42/368 reads (11%) | called by mutect2, pindel, varscan2
- ACOT12 | c.30C>A p.V10= | Silent (SNP) | VAF 64/263 reads (24%) | called by muse, mutect2, varscan2
- AKAP3 | c.1902G>A p.A634= | Silent (SNP) | VAF 34/408 reads (8%) | catalogued as rs753087718, COSV57417730; called by muse, mutect2
- ANGPT1 | c.789T>C p.N263= | Silent (SNP) | VAF 13/330 reads (4%) | called by muse, mutect2
- APC2 | c.4575A>T p.P1525= | Silent (SNP) | VAF 22/423 reads (5%) | called by muse, mutect2
- ATP2B4 | c.60G>T p.G20= | Silent (SNP) | VAF 96/407 reads (24%) | called by muse, mutect2, varscan2
- C2orf16 | c.1659C>T p.A553= | Silent (SNP) | VAF 29/350 reads (8%) | called by muse, mutect2
- COL6A6 | c.2424A>G p.L808= | Silent (SNP) | VAF 28/265 reads (11%) | called by muse, mutect2, varscan2
- CSNKA2IP | c.1533T>C p.S511= | Silent (SNP) | VAF 75/286 reads (26%) | catalogued as COSV101359566; called by muse, mutect2, varscan2
- CXorf66 | c.834T>C p.T278= | Silent (SNP) | VAF 15/225 reads (7%) | called by muse, mutect2
- DCSTAMP | c.378T>C p.T126= | Silent (SNP) | VAF 34/450 reads (8%) | catalogued as COSV52577857; called by muse, mutect2
- DERA | c.336A>C p.A112= | Silent (SNP) | VAF 14/310 reads (5%) | called by muse, mutect2
- DMRTB1 | c.300G>A p.P100= | Silent (SNP) | VAF 57/435 reads (13%) | catalogued as rs949279620; called by mutect2, varscan2
- DOCK7 | c.3279T>C p.L1093= (on ENST00000635253 / NM_001367561.1; = p.L1062= on NM_033407.3) | Silent (SNP) | VAF 14/170 reads (8%) | catalogued as COSV99224567; called by muse, mutect2
- EHBP1L1 | c.1512G>A p.Q504= | Silent (SNP) | VAF 18/613 reads (3%) | called by muse, mutect2
- ELFN1 | c.924G>A p.T308= | Silent (SNP) | VAF 41/483 reads (8%) | catalogued as rs746104771, COSV70034123; called by muse, mutect2
- EMB | c.702T>C p.S234= | Silent (SNP) | VAF 26/471 reads (6%) | catalogued as COSV57480359; called by muse, mutect2
- FAT2 | c.9741C>T p.G3247= | Silent (SNP) | VAF 56/414 reads (14%) | catalogued as rs772008822; called by muse, mutect2, varscan2
- FRG2C | c.69T>A p.P23= | Silent (SNP) | VAF 57/879 reads (6%) | called by muse, mutect2
- FST | c.798G>T p.R266= | Silent (SNP) | VAF 54/346 reads (16%) | catalogued as COSV56814867; called by muse, mutect2, varscan2
- GPR132 | c.165G>T p.L55= | Silent (SNP) | VAF 34/551 reads (6%) | catalogued as COSV100317786; called by muse, mutect2
- HIPK2 | c.1968C>T p.I656= | Silent (SNP) | VAF 47/378 reads (12%) | catalogued as rs750107658, COSV61233141; called by muse, mutect2, varscan2
- HMCN1 | c.1422G>A p.Q474= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as COSV54944001; called by muse, mutect2
- HSPA8 | c.1560G>A p.Q520= | Silent (SNP) | VAF 69/400 reads (17%) | called by muse, mutect2, varscan2
- IRX1 | c.642G>A p.P214= | Silent (SNP) | VAF 35/422 reads (8%) | catalogued as rs765999859, COSV57362623; called by muse, mutect2
- KCNA5 | c.897C>T p.N299= | Silent (SNP) | VAF 115/384 reads (30%) | catalogued as rs773608258, COSV52905503; called by muse, mutect2, varscan2
- KIAA1614 | c.690C>T p.I230= | Silent (SNP) | VAF 18/436 reads (4%) | called by muse, mutect2
- KRBOX1 | c.199C>T p.L67= | Silent (SNP) | VAF 40/319 reads (13%) | called by muse, mutect2, varscan2
- LAMA1 | c.8571C>A p.I2857= | Silent (SNP) | VAF 33/340 reads (10%) | called by muse, mutect2, varscan2
- LRRC6 | c.433T>C p.L145= | Silent (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- MLXIP | c.1275G>A p.P425= | Silent (SNP) | VAF 123/499 reads (25%) | catalogued as rs374527589; called by muse, mutect2, varscan2
- NAA11 | c.666A>G p.S222= | Silent (SNP) | VAF 19/284 reads (7%) | catalogued as COSV54513958; called by muse, mutect2
- OR6V1 | c.459C>A p.A153= | Silent (SNP) | VAF 18/570 reads (3%) | called by muse, mutect2
- RHAG | c.192G>T p.G64= | Silent (SNP) | VAF 83/412 reads (20%) | called by muse, mutect2, varscan2
- RPS3A | c.147C>T p.V49= | Silent (SNP) | VAF 25/303 reads (8%) | called by muse, mutect2
- RTN1 | c.993C>T p.I331= | Silent (SNP) | VAF 42/272 reads (15%) | called by muse, mutect2, varscan2
- RTP1 | c.486C>T p.R162= | Silent (SNP) | VAF 36/590 reads (6%) | catalogued as rs752112047; called by muse, mutect2
- SLC4A11 | c.1212C>T p.A404= | Silent (SNP) | VAF 54/209 reads (26%) | catalogued as rs770579844; called by muse, mutect2, varscan2
- SLITRK1 | c.654T>C p.C218= | Silent (SNP) | VAF 92/360 reads (26%) | called by muse, mutect2, varscan2
- SP140 | c.358C>T p.L120= | Silent (SNP) | VAF 27/356 reads (8%) | called by muse, mutect2
- SRRD | c.672C>T p.A224= | Silent (SNP) | VAF 84/341 reads (25%) | called by muse, mutect2, varscan2
- SYNE1 | c.15198C>G p.T5066= (on ENST00000367255 / NM_182961.4; = p.T4995= on NM_033071.3) | Silent (SNP) | VAF 44/401 reads (11%) | catalogued as COSV55037671; called by muse, mutect2, varscan2
- TMEM131L | c.3006G>A p.E1002= | Silent (SNP) | VAF 54/420 reads (13%) | called by muse, mutect2, varscan2
- TRAK2 | c.456G>A p.E152= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as rs369163139; called by muse, mutect2
- TRDMT1 | c.450T>C p.S150= | Silent (SNP) | VAF 17/135 reads (13%) | catalogued as COSV58320731; called by muse, mutect2, varscan2
- TRIML1 | c.78A>G p.P26= | Silent (SNP) | VAF 73/386 reads (19%) | called by muse, mutect2, varscan2
- TRIO | c.4230G>A p.Q1410= | Silent (SNP) | VAF 8/231 reads (3%) | called by muse, mutect2
- TUBGCP6 | c.2373G>A p.R791= | Silent (SNP) | VAF 82/262 reads (31%) | catalogued as COSV50544767; called by muse, mutect2, varscan2
- VCAN | c.1359A>G p.S453= | Silent (SNP) | VAF 42/432 reads (10%) | called by muse, mutect2
- VPS37D | c.609C>T p.A203= | Silent (SNP) | VAF 69/324 reads (21%) | catalogued as rs1456567567; called by muse, varscan2
- DCAF13 | chr8:103415276 C>G | 5'Flank (SNP) | VAF 30/428 reads (7%) | catalogued as rs755062543; called by muse, mutect2
- KCNQ1 | c.1394-11532C>T | Intron (SNP) | VAF 54/312 reads (17%) | catalogued as rs975752832; called by muse, mutect2, varscan2
- PHLPP2 | c.-7+514C>T | Intron (SNP) | VAF 28/218 reads (13%) | called by muse, mutect2, varscan2
- PLEC | c.524-3717A>T | Intron (SNP) | VAF 55/262 reads (21%) | called by muse, mutect2, varscan2
- REXO1L1P | n.874G>A | RNA (SNP) | VAF 24/800 reads (3%) | catalogued as rs1311628583; called by muse, mutect2
- STARD8 | c.-35T>C | 5'UTR (SNP) | VAF 19/264 reads (7%) | called by muse, mutect2
- TTN | c.34523-902A>C | Intron (SNP) | VAF 16/320 reads (5%) | catalogued as rs554529099; called by muse, mutect2
